Somatic mutation profile of tumor specimen C3L-05027-01 (aliquot CPT0262740009) from CPTAC case C3L-05027, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 64.8 years (23,678 days).
Specimen C3L-05027-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c499b6b2-c7c3-4217-b839-7242a91d8536.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05027-31 (Blood Derived Normal), aliquot CPT0263800002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e175dd96-61fb-434a-b077-436752db9f94

The open-access MAF lists 42 somatic variants for this specimen: 31 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 8, Frame Shift Del 2, Frame Shift Ins 2, 5'UTR 1, Intron 1, 3'UTR 1, Nonsense Mutation 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH10 | c.2179G>A p.A727T | Missense Mutation (SNP) | VAF 107/294 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); catalogued as rs763581492, COSV52589090, COSV52594161; called by muse, mutect2, varscan2
- DHX29 | c.1940G>A p.G647D | Missense Mutation (SNP) | VAF 52/181 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99287379; called by muse, mutect2, varscan2
- DSC2 | c.1934C>T p.S645L | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs1339580561; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FSIP2 | c.3373C>G p.P1125A | Missense Mutation (SNP) | VAF 80/258 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.164); catalogued as COSV58102999; called by muse, mutect2, varscan2
- GRIA4 | c.502C>T p.Q168* | Nonsense Mutation (SNP) | VAF 43/168 reads (26%) | catalogued as COSV56879890; called by muse, mutect2, varscan2
- NAV3 | c.4442-1G>C p.X1481_splice | Splice Site (SNP) | VAF 16/134 reads (12%) | catalogued as COSV99897628; called by muse, varscan2
- NCAN | c.3349C>T p.R1117C | Missense Mutation (SNP) | VAF 127/327 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373196301; called by muse, mutect2, varscan2
- NOS1 | c.3142C>A p.L1048I | Missense Mutation (SNP) | VAF 89/410 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.305); catalogued as rs746992969, COSV100501590; called by muse, mutect2, varscan2
- NPAP1 | c.146G>T p.G49V | Missense Mutation (SNP) | VAF 172/671 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.072); catalogued as COSV100275306; called by muse, mutect2, varscan2
- NTN5 | c.1120G>A p.V374M | Missense Mutation (SNP) | VAF 92/278 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs1340258179; called by muse, mutect2, varscan2
- ZNF195 | c.70del p.A24Lfs*9 | Frame Shift Del (DEL) | VAF 28/147 reads (19%) | catalogued as COSV50003322; called by mutect2, pindel, varscan2
- AIRE | c.1091C>G p.T364S | Missense Mutation (SNP) | VAF 78/243 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.138); called by muse, mutect2
- CSMD3 | c.2398C>T p.L800F (on ENST00000297405 / NM_001363185.1; = p.L696F on NM_052900.3) | Missense Mutation (SNP) | VAF 182/344 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DMD | c.5359A>G p.N1787D | Missense Mutation (SNP) | VAF 84/109 reads (77%) | SIFT tolerated (0.38); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- HNRNPL | c.1036G>A p.G346S | Missense Mutation (SNP) | VAF 112/364 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ILVBL | c.103C>G p.R35G | Missense Mutation (SNP) | VAF 125/368 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- INAVA | c.1573G>A p.V525M | Missense Mutation (SNP) | VAF 41/279 reads (15%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- KCNK6 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 131/388 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LAMA2 | c.3427_3433del p.I1143Vfs*37 | Frame Shift Del (DEL) | VAF 102/143 reads (71%) | called by mutect2, pindel*, varscan2
- MAGI3 | c.4434G>T p.E1478D | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PSMA8 | c.219G>T p.M73I | Missense Mutation (SNP) | VAF 63/169 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- PTPDC1 | c.2243A>C p.D748A (on ENST00000375360 / NM_177995.3; = p.D800A on NM_152422.4) | Missense Mutation (SNP) | VAF 69/124 reads (56%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RAVER1 | c.444_446del p.F148_E149delinsL | In Frame Del (DEL) | VAF 155/364 reads (43%) | called by mutect2, pindel*, varscan2
- RC3H1 | c.3353A>C p.D1118A | Missense Mutation (SNP) | VAF 93/249 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- SCARF2 | c.241dup p.E81Gfs*47 | Frame Shift Ins (INS) | VAF 33/290 reads (11%) | called by mutect2, pindel, varscan2
- SNX21 | c.847dup p.L283Pfs*25 | Frame Shift Ins (INS) | VAF 224/467 reads (48%) | called by mutect2, varscan2
- SOX3 | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 150/193 reads (78%) | SIFT tolerated (0.06); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- STON2 | c.1735G>A p.A579T (on ENST00000649389 / NM_001366849.2; = p.A522T on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/262 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- WDFY4 | c.686G>T p.R229L | Missense Mutation (SNP) | VAF 67/190 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ZNF276 | c.590A>G p.H197R (on ENST00000443381 / NM_001113525.2; = p.H122R on NM_152287.4) | Missense Mutation (SNP) | VAF 145/355 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF726 | c.1106A>T p.Y369F | Missense Mutation (SNP) | VAF 24/205 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ADAM23 | c.2472C>T p.F824= | Silent (SNP) | VAF 94/252 reads (37%) | catalogued as rs767066735, COSV52226395, COSV52228602; called by muse, mutect2, varscan2
- CDC42BPB | c.783G>A p.E261= | Silent (SNP) | VAF 144/324 reads (44%) | catalogued as rs751949292; called by muse, mutect2, varscan2
- GPR157 | c.891C>T p.C297= | Silent (SNP) | VAF 113/356 reads (32%) | catalogued as rs1239469880; called by muse, mutect2, varscan2
- L3MBTL1 | c.459C>T p.G153= (on ENST00000418998 / NM_001377303.1; = p.G63= on NM_015478.7) | Silent (SNP) | VAF 139/600 reads (23%) | called by muse, mutect2, varscan2
- OTUD7B | c.1803T>A p.T601= | Silent (SNP) | VAF 99/243 reads (41%) | called by muse, mutect2, varscan2
- REV3L | c.3816T>C p.S1272= | Silent (SNP) | VAF 178/246 reads (72%) | called by muse, mutect2, varscan2
- SLC22A7 | c.384T>C p.I128= | Silent (SNP) | VAF 78/338 reads (23%) | called by muse, mutect2, varscan2
- TGFBRAP1 | c.1344C>A p.I448= | Silent (SNP) | VAF 87/290 reads (30%) | called by muse, mutect2, varscan2
- C6orf136 | c.72+437dup | Intron (INS) | VAF 331/1138 reads (29%) | called by mutect2, pindel, varscan2
- PEX16 | c.*135G>A | 3'UTR (SNP) | VAF 106/285 reads (37%) | catalogued as rs749581838; called by muse, mutect2, varscan2
- TERT | c.-57A>C | 5'UTR (SNP) | VAF 115/326 reads (35%) | catalogued as rs878855297, CR131339, COSV57196893; ClinVar: uncertain significance; called by mutect2, varscan2
